Somatic mutation profile of tumor specimen MP2PRT-PAPSZG-TMP1-A (aliquot MP2PRT-PAPSZG-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPSZG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,023 days).
Specimen MP2PRT-PAPSZG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78757684-b050-4673-a5c9-b3219f5b2f39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPSZG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPSZG-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54cc02c0-cead-49f0-8773-628f8c6b977d

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 17/212 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- FLT3 | c.1735_1736insGAGACTCGG p.M578_V579insGDS | In Frame Ins (INS) | VAF 40/165 reads (24%) | catalogued as COSV54054896, COSV54068636; called by mutect2, pindel, varscan2
- KCNA2 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 23/348 reads (7%) | catalogued as rs763353895, COSV60370708; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- MAPT | c.955C>T p.R319W (on ENST00000262410 / NM_001377265.1; = p.R244W on NM_016835.4) | Missense Mutation (SNP) | VAF 54/947 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs141636376; called by muse, mutect2
- PKP1 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 48/448 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569372122, COSV55824543; called by muse, mutect2, varscan2
- PTPRN2 | c.2545G>A p.A849T | Missense Mutation (SNP) | VAF 75/299 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs769738694, COSV66104998; called by muse, mutect2, varscan2
- RNF128 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 31/714 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99718262; called by muse, mutect2
- TTN | c.22735G>A p.E7579K (on ENST00000591111; = p.E6652K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/105 reads (47%) | PolyPhen possibly damaging (0.749); catalogued as rs786205400, COSV60131729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR87 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 96/227 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459999169, COSV58203037; called by muse, mutect2, varscan2
- ZFAT | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 171/372 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs770340063; called by muse, mutect2, varscan2
- AKAP6 | c.5809G>C p.A1937P | Missense Mutation (SNP) | VAF 17/253 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- FAM47A | c.116G>T p.R39M | Missense Mutation (SNP) | VAF 152/720 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, varscan2
- HYDIN | c.2089G>T p.A697S | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IL21R | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 163/392 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC22 | c.3772G>T p.V1258F | Missense Mutation (SNP) | VAF 34/777 reads (4%) | SIFT deleterious (0.03); called by muse, mutect2
- CFAP161 | c.198C>T p.Y66= | Silent (SNP) | VAF 69/180 reads (38%) | catalogued as rs376487839; called by muse, mutect2, varscan2
- CRIP2 | c.297G>A p.E99= | Silent (SNP) | VAF 179/576 reads (31%) | catalogued as rs1187336791; called by muse, mutect2, varscan2
- KLHL17 | c.1749G>A p.G583= | Silent (SNP) | VAF 142/353 reads (40%) | called by muse, mutect2, varscan2
- MINDY4 | c.1752C>T p.R584= | Silent (SNP) | VAF 108/240 reads (45%) | catalogued as rs774483934; called by muse, mutect2, varscan2
- PCDHA3 | c.1296G>A p.S432= | Silent (SNP) | VAF 27/293 reads (9%) | catalogued as rs782338316; called by muse, mutect2
